Surgical pathology report (de-identified scan), TCGA case TCGA-L9-A7SV, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Candler, specimen TCGA-L9-A7SV-01A (Primary Tumor).

[page 1 of 5]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 1

PATIENT: [REDACTED]

ACCT #: [REDACTED]

LOC: [REDACTED]

REG DR: [REDACTED]

AGE/SX: [REDACTED]

ROOM: [REDACTED]

DOB: [REDACTED]

BED: [REDACTED]

STATUS: [REDACTED]

SPEC #: [REDACTED]

RECD:

STATUS:

COLL:

TIME IN FORMALIN:

hrs.

COLD ISCHEMIA TIME:

mins.

CLINICAL INFORMATION:

Pre-Op Diagnosis: Lung CA

Remarks:

Specimen(s):	A. Level 7	H. Level 10 lymph node
	B. Level R4	I. New bronchial margins
	C. Chest wall lymph node	J. Level 11
	D. Left upper lobe lesion	K. Level 5
	E. Level 5 lymph node	L. Level 6
	F. Level 10 lymph nodes	M. Level 4
	G. Left lower lobe bronchial margin	N. Level 10

MICROSCOPIC DIAGNOSIS

- A. LEVEL 7:
- REACTIVE LYMPH NODE
- B. LEVEL R4:
- REACTIVE LYMPH NODE
- C. CHEST WALL LYMPH NODE:
- REACTIVE LYMPH NODE
- D. LEFT UPPER LOBE LESION:
- APICAL SCAR WITH CALCIFICATIONS
- E. LEVEL 5 LYMPH NODE:
- REACTIVE LYMPH NODE
- F. LEVEL 10 LYMPH NODES:
- REACTIVE LYMPH NODE
- G. LEFT LOWER LOBE BRONCHIAL MARGIN:
- ADENOCARCINOMA
- SEE COMMENT FOR DETAILS
- H. LEVEL 10 LYMPH NODE:
- REACTIVE LYMPH NODE
- I. NEW BRONCHIAL MARGINS:
- REACTIVE LYMPH NODE
- J. LEVEL 11:

ICD-O-3
Adenocarcinoma NOS 8140/3
Site Lung, lower lobe C34.3
JW 10/10/13

[page 2 of 5]
RUN DATE: [REDACTED]
RUN TIME:
RUN USER: [REDACTED]

PAGE 2

SPEC #: [REDACTED] PATIENT: [REDACTED] (Continued)

MICROSCOPIC DIAGNOSIS (Continued)

- REACTIVE LYMPH NODE

K. LEVEL 5:

- REACTIVE LYMPH NODE

L. LEVEL 6:

- REACTIVE LYMPH NODE

M. LEVEL 4:

- REACTIVE LYMPH NODE

N. LEVEL 10:

- NON-NEOPLASTIC LUNG TISSUE
- LYMPH NODE NOT IDENTIFIED

COMMENT(S)

COLLEGE OF AMERICAN PATHOLOGISTS' PROTOCOL FOR EXAMINATION OF SPECIMENS WITH PRIMARY NON SMALL-CELL CARCINOMA OF THE LUNG, BASED ON AJCC/UICC TNM, 7TH EDITION
The following classification should be adjusted based on additional clinical information.

SPECIMEN:	Lung
PROCEDURE:	Lobectomy
SPECIMEN INTEGRITY:	Intact
SPECIMEN LATERALITY:	Left
TUMOR SITE:	Lower lobe
TUMOR SIZE:	Greatest dimension: 3.7 cm
TUMOR FOCALITY:	Unifocal
HISTOLOGIC TYPE:	Adenocarcinoma
HISTOLOGIC GRADE:	G2
VISCERAL PLEURA INVASION:	Not identified
TUMOR EXTENSION:	Not applicable
MARGINS:	All margins uninvolved by invasive carcinoma Distance of invasive carcinoma from closest margin: 3 mm, bronchial/vascular
TREATMENT EFFECT:	Not applicable
LYMPH-VASCULAR INVASION:	Present
PATHOLOGIC STAGING:	Primary tumor: pT2a Regional lymph nodes: pN1 Number of lymph nodes examined: 15 Number of lymph nodes involved: 1 (peribronchial attached to lobectomy specimen) Distant metastasis: not applicable
ADDITIONAL PATHOLOGIC FINDINGS:	Emphysematous changes

** CONTINUED ON NEXT PAGE **

[page 3 of 5]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 3

SPEC #: PATIENT: (Continued)

GROSS DESCRIPTION:

A is labeled "level 7", is received in the unfixed state and consists of two pieces of gauze from which the surface is scraped tan-black fragments of lymph node aggregating to 1 cm, entirely frozen in block A1.

B is received in the unfixed state in the operating room labeled "level R4". Multiple black-tan pieces of lymph node aggregate to 1.2 cm, entirely frozen in block B1.

C is received in formalin labeled with the patient's name and "chest wall lymph node" are two anthracotic lymphoid tissue fragments which are 0.3 and 0.4 cm, submitted in toto in cassette C1.

D is received in the unfixed state in the operating room labeled "left wedge upper lobe". The single wedge of lung measures 5 x 1 x 1 cm. The staple line is removed. The parenchyma is blackish-red. There is an ill-defined 0.6 mm firm area in this area beneath the pleura. This lesion is entirely frozen in block D1. Additional lung is submitted in cassette 2.

E. Received in formalin labeled with the patient's name and "level 5 lymph node" is a 1.5 x 0.8 x 0.3 cm gray-black, focally disrupted anthracotic lymph node. The node is submitted in toto in cassette E1.

F. Received in formalin labeled with the patient's name and "level 10 lymph node" are two blackened, delicate linear anthracotic lymph nodes. The nodes average 1.0 x 0.7 x 0.3 cm, submitted in toto in cassette F1.

G. Received fresh for frozen section diagnosis and for tissue banking labeled "left lower lobe" is a 230 gram, 14.0 x 13.0 x 4.5 cm lobe of lung. The pleural surface is pink-tan to red and congested with diffuse anthracotic marbling. The staples are removed, and the bronchial margin is sampled for frozen section diagnosis. The pleural surface is puckered in the region of the hilum. This region is inked blue and a section is placed perpendicular down the length of the bronchus. There is a 3.7 x 3.3 x 3.0 cm tumor mass present. The tumor is at the hilum and involves the bronchus. The tumor comes to within 1.6 cm of the bronchial margin at the bronchus, and adjacent to the bronchus is 0.3 cm to the stapled bronchial margin. The tumor focally abuts and puckers the pleura and surrounds the hilar vessels. The remainder of the parenchyma is congested predominantly in the central aspect of the specimen. The parenchyma appears spongy superiorly and becomes consolidated surrounding the hilum. The basilar parenchyma has a more normal, unremarkable appearance. No additional lesions or tumor-like masses are identified. Tumor is selected and sampled for tissue banking, and the bronchial margin is submitted for frozen section diagnosis. The specimen is sampled as labeled:

- G1 - bronchial margin frozen section residue
- G2 - vascular margins and hilar lymph nodes
- G3 - sections showing tumor to puckered pleura and bronchus
- G4-G5 - additional perpendicular section of tumor extending up bronchus
- G6-G7 - additional sections of tumor to pleura and bronchus
- G8-G9 - sections of tumor to additional hilar structures to include vessels
- G10 - sections from superior lower lobe
- G11 - sections of mid lower lobe (adjacent to tumor)
- G12 - inferior, basilar aspect of lower lobe sampled

** CONTINUED ON NEXT PAGE **

[page 4 of 5]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 4

SPEC #:

PATIENT:

(Continued)

GROSS DESCRIPTION: (Continued)

H. Received in formalin labeled with the patient's name and "level 10 lymph node" is a 1.0 x 0.7 x 0.3 cm anthracotic lymph node, submitted in toto in cassette H1.

I. Labeled "new bronchial margin" are two tissue fragments with numerous embedded staples. The tissue fragments include a 0.6 x 0.3 x 0.1 cm portion of focally anthracotic to pink-tan soft tissue and a nodular, linear 1.0 x 0.5 x 0.4 cm anthracotic lymph node. The staples are removed, and the tissues are submitted in toto for frozen section diagnosis with the frozen section residue in cassette I1.

J. Labeled "level 11 lymph nodes". Two black lymph nodes measure 0.5 and 0.8 cm, entirely submitted in cassette J.

K. Labeled "level 5 lymph node". One irregular shaped black lymph node with some tannish tissue measures 1.5 cm, entirely submitted in cassette K.

L. Labeled "level 6 lymph nodes". Two black nodes measure 0.6 cm, entirely submitted in cassette L.

M. Labeled "level 4 lymph node". A single floating 1.1 cm soft tan piece of tissue is entirely submitted, cassette M.

N. Labeled "level 10 lymph node". A single 1.4 cm lymph node, has some staples removed from the outer surface. The staple line is removed. The specimen measures 9 mm, entirely submitted in cassette N.

INTRAOPERATIVE CONSULTATION:
FROZEN SECTIONS:

- A. LEVEL 7 LYMPH NODE:
- REACTIVE LYMPH NODE FRAGMENTS
- B. LEVEL R4 LYMPH NODE:
- REACTIVE LYMPH NODE FRAGMENTS
- D. LEFT UPPER LOBE WEDGE RESECTION:
- APICAL SCAR WITH CALCIFICATIONS
- NO EVIDENCE OF MALIGNANCY
- G. LEFT LOWER LOBE BRONCHUS WITH MARGIN:
- MARGIN NEGATIVE
- I. NEW BRONCHIAL MARGIN:
- REACTIVE LYMPH NODE

** CONTINUED ON NEXT PAGE **

[page 5 of 5]
RUN DATE:
RUN TIME:
RUN USER:

PAGE 5

SPEC #: PATIENT: (Continued)

PHOTO DOCUMENTATION

Image Picture Copy Error

Signed (signature on file)

** END OF REPORT **

Criteria	W 9/23/13	Yes	No
Tumor Discrepancy			✓
Case (circle):	QUALIFIED		

Source: NCI Genomic Data Commons file 470f0651-f3de-48a1-97ed-c9185545cd23 (TCGA-L9-A7SV.C6014F3D-A7C4-455E-9DC8-A59244C81DF7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).